Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51J, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51J-06A (Metastatic).

DIAGNOSIS

(A) SOFT TISSUE, SUPERFICIAL INGUINAL MASS:
METASTATIC MELANOMA TO SOFT TISSUE
Largest tumor deposit size: 40 x 30 mm (PER GROSS DESCRIPTION)
SEE COMMENT.

COMMENT

A completely replaced lymph node can not be excluded.

GROSS DESCRIPTION

(A) LEFT SUPERFICIAL INGUINAL MASS, STERILE – One pale-gray mass (4.0 x 3.0 x 2.1 cm) with a pale-gray, homogenous and nodular cut surface. Approximately 95% of the specimen is submitted for study in sterile condition and representative cross section of the specimen is submitted for tissue processing in A.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

M-87206

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration.
Entire report and diagnosis completed by:

these tests have not been

-----END OF REPORT-----

II/IIIA Discrepancy		/
Prox. Malignancy History		/
Dual/Sync. Primary Malignancy		/

11/6/12

Source: NCI Genomic Data Commons file 910d0550-5778-4827-80f2-29443ae22121 (TCGA-D3-A51J.B244C527-3631-4829-B8E3-969D263CD08F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).